CCDI case PBCIRT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dd9a1938-c121-4518-a5ca-14c1f2cd3c58

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 5.0 years (1,842 days).

Biospecimens (3 samples)
- Sample 0DSR4W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSR51: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSR5D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
